Somatic mutation profile of tumor specimen TCGA-99-7458-01A (aliquot TCGA-99-7458-01A-11D-2036-08) from TCGA case TCGA-99-7458, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 74.9 years (27,359 days).
Specimen TCGA-99-7458-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78a71c8d-9b98-41b1-a206-3123f7cdddd7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-99-7458-10A (Blood Derived Normal), aliquot TCGA-99-7458-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73a2cb7b-27e6-4f65-94da-9c835ebf0921

The open-access MAF lists 523 somatic variants for this specimen: 400 protein-altering or splice-affecting, 112 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 335, Silent 112, Nonsense Mutation 28, Frame Shift Del 18, Splice Site 11, RNA 5, Frame Shift Ins 5, Intron 3, 3'UTR 2, In Frame Del 2, 5'UTR 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CD40LG | c.761C>A p.T254K | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs193922136, CM960264, COSV101033584, COSV65699024; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 10/51 reads (20%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AASS | c.2165G>T p.R722L | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100741736; called by muse, mutect2
- ABCA10 | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as rs766856480, COSV99287567; called by muse, mutect2, varscan2
- ABCA8 | c.1179C>A p.D393E | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.048); catalogued as COSV52210584; called by muse, mutect2, varscan2
- ABCC11 | c.3345G>T p.M1115I | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62323519, COSV62325540; called by muse, mutect2, varscan2
- AC136428.1 | c.194A>G p.E65G | Missense Mutation (SNP) | VAF 58/459 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV101434934; called by muse, mutect2, varscan2
- AC136428.1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 59/454 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV101434935; called by muse, mutect2, varscan2
- ACAN | c.5626G>A p.G1876R | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV61368288; called by muse, mutect2, varscan2
- ACE2 | c.100C>A p.H34N | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53027349; called by muse, mutect2, varscan2
- ACTN2 | c.1027A>T p.I343F | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV63977871; called by muse, mutect2, varscan2
- ACTR8 | c.1597A>T p.S533C | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51638335; called by muse, mutect2, varscan2
- ADAMTS1 | c.1914del p.S639Vfs*40 | Frame Shift Del (DEL) | VAF 21/120 reads (18%) | catalogued as COSV99536265; called by mutect2, pindel, varscan2
- ADAMTS16 | c.2279-1G>T p.X760_splice | Splice Site (SNP) | VAF 36/146 reads (25%) | catalogued as COSV56983043, COSV57005224; called by muse, varscan2
- ADAMTS8 | c.2471C>A p.T824N | Missense Mutation (SNP) | VAF 48/247 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV57297127; called by muse, mutect2, varscan2
- ADGRE1 | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.77); catalogued as COSV51680313; called by muse, mutect2, varscan2
- ADGRG4 | c.1849G>T p.G617* | Nonsense Mutation (SNP) | VAF 16/98 reads (16%) | catalogued as COSV54965424; called by muse, mutect2, varscan2
- ADGRG4 | c.3322G>T p.E1108* | Nonsense Mutation (SNP) | VAF 47/246 reads (19%) | catalogued as COSV54965433; called by muse, mutect2, varscan2
- ADGRL3 | c.873G>C p.E291D (on ENST00000506720 / NM_001322402.2; = p.E223D on NM_015236.6) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV72272904; called by muse, mutect2, varscan2
- AFF1 | c.3332C>T p.A1111V | Missense Mutation (SNP) | VAF 90/490 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57123426; called by muse, mutect2, varscan2
- AHNAK2 | c.8124G>C p.Q2708H | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV60928599; called by muse, mutect2, varscan2
- AHNAK2 | c.4600G>A p.G1534R | Missense Mutation (SNP) | VAF 58/342 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.415); catalogued as rs1415437708, COSV60928618; called by muse, mutect2
- AKAP6 | c.4606A>G p.M1536V | Missense Mutation (SNP) | VAF 4/84 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.015); catalogued as COSV55230384; called by muse, mutect2
- ALB | c.1765G>T p.E589* | Nonsense Mutation (SNP) | VAF 15/96 reads (16%) | catalogued as CM900419, COSV55741899; called by muse, mutect2, varscan2
- AMER1 | c.1412A>G p.Y471C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57666813; called by muse, varscan2
- AMMECR1 | c.397T>A p.F133I | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53320018, COSV99467166; called by muse, mutect2, varscan2
- AMPH | c.1504G>A p.G502R | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.166); catalogued as rs759265550, COSV100341675, COSV57754878; called by muse, mutect2, varscan2
- ANK2 | c.670-1G>T p.X224_splice | Splice Site (SNP) | VAF 13/77 reads (17%) | catalogued as COSV52184628; called by muse, mutect2, varscan2
- APOOL | c.739G>T p.D247Y | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60578194; called by muse, mutect2
- ARFGEF3 | c.3959G>T p.G1320V | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV52469279; called by muse, mutect2, varscan2
- ARID1B | c.5133G>T p.L1711F | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV51678437; called by muse, mutect2, varscan2
- ARID1B | c.6004G>T p.D2002Y | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51678454; called by muse, mutect2, varscan2
- ARSF | c.627C>A p.S209R | Missense Mutation (SNP) | VAF 14/116 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as COSV63840457, COSV63840896; called by muse, mutect2, varscan2
- AS3MT | c.743G>T p.G248V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV54918747; called by muse, mutect2, varscan2
- ASB11 | c.808C>A p.P270T | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV60356461; called by muse, mutect2, varscan2
- ASPM | c.8876G>T p.C2959F | Missense Mutation (SNP) | VAF 76/261 reads (29%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.972); catalogued as COSV54137533; called by muse, mutect2, varscan2
- ASXL3 | c.2341C>G p.P781A | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs756171085, COSV52477840; called by muse, mutect2
- ATRNL1 | c.1847A>T p.K616M | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV61815257; called by muse, mutect2, varscan2
- ATRX | c.4757C>A p.P1586Q | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.577); catalogued as COSV64882508; called by muse, mutect2
- BCKDK | c.313C>A p.R105S | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54890370, COSV54893713; called by muse, mutect2
- BCORL1 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.634); catalogued as COSV54405677; called by muse, mutect2, varscan2
- BCORL1 | c.2977C>T p.H993Y | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1345386158, COSV54392889, COSV99500396; called by muse, mutect2, varscan2
- BUD31 | c.261C>G p.N87K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV52867197; called by muse, mutect2, varscan2
- C17orf75 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 27/176 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56754040; called by muse, mutect2, varscan2
- C3orf20 | c.2003T>G p.L668R | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53788891; called by muse, mutect2
- CABLES1 | c.1498G>A p.E500K (on ENST00000256925 / NM_001100619.2; = p.E235K on NM_138375.2) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs370752492; called by muse, mutect2, varscan2
- CACNA1B | c.5161C>A p.L1721I | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53145778, COSV53152210; called by muse, mutect2, varscan2
- CACNA1G | c.4786G>T p.D1596Y | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV61737356; called by muse, mutect2, varscan2
- CALB1 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV55367674, COSV55369139; called by muse, mutect2
- CARMIL2 | c.248A>T p.Q83L | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV58023104, COSV58031300; called by muse, mutect2, varscan2
- CCKAR | c.1244G>T p.R415M | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV55163664; called by muse, mutect2, varscan2
- CCNB3 | c.2810C>T p.P937L | Missense Mutation (SNP) | VAF 15/111 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV52079024; called by muse, mutect2, varscan2
- CD33 | c.999G>T p.E333D | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as COSV51804368; called by muse, mutect2, varscan2
- CDH17 | c.1095T>A p.H365Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.04); catalogued as rs768104607, COSV50338842, COSV99218005; called by muse, mutect2, varscan2
- CDH19 | c.1918C>A p.Q640K | Missense Mutation (SNP) | VAF 23/216 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV50954246; called by muse, mutect2, varscan2
- CDK8 | c.1131G>C p.Q377H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.215); catalogued as COSV67422886; called by muse, mutect2, varscan2
- CDYL | c.763G>T p.G255W (on ENST00000328908 / NM_001368125.1; = p.G201W on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV59359826, COSV59361591; called by muse, mutect2, varscan2
- CENPE | c.1115A>T p.E372V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV54388854; called by mutect2, varscan2
- CEP55 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | catalogued as COSV65185805; called by muse, mutect2, varscan2
- CETN2 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.941); catalogued as COSV64745099; called by muse, mutect2, varscan2
- CFAP54 | c.7493C>T p.S2498F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.101); catalogued as COSV61574861; called by muse, mutect2
- CFHR2 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 14/112 reads (13%) | catalogued as COSV66382046; called by muse, mutect2, varscan2
- CLCA4 | c.2006C>A p.T669K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55370773; called by muse, mutect2
- CLEC6A | c.452G>T p.W151L | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101165677, COSV65986936; called by muse, mutect2, varscan2
- CLEC6A | c.453G>T p.W151C | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV101165601; called by muse, mutect2, varscan2
- CNGA3 | c.1395G>T p.K465N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV55627769; called by muse, mutect2, varscan2
- CNTNAP5 | c.2506G>T p.D836Y | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV101444274, COSV70508972; called by muse, mutect2, varscan2
- COL11A1 | c.3025-1G>T p.X1009_splice | Splice Site (SNP) | VAF 15/84 reads (18%) | catalogued as COSV62195317; called by muse, mutect2, varscan2
- COL11A1 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1158320165, COSV62195322; called by muse, mutect2, varscan2
- COL12A1 | c.6058G>T p.G2020C | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV59406240; called by muse, mutect2, varscan2
- COL15A1 | c.2725G>T p.G909W | Missense Mutation (SNP) | VAF 68/200 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66643225, COSV66648675; called by muse, mutect2, varscan2
- COL7A1 | c.1580C>A p.S527Y | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.93); catalogued as COSV60402219; called by muse, mutect2, varscan2
- COLQ | c.868A>G p.R290G | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV67525829; called by muse, mutect2, varscan2
- COMMD1 | c.353G>C p.G118A | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.02); catalogued as COSV61280066; called by muse, mutect2, varscan2
- CRACD | c.2581G>T p.D861Y | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51729659, COSV51730395; called by muse, mutect2, varscan2
- CSMD3 | c.5867C>A p.P1956H (on ENST00000297405 / NM_001363185.1; = p.P1852H on NM_052900.3) | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52299273; called by muse, mutect2, varscan2
- CSMD3 | c.2334A>T p.K778N (on ENST00000297405 / NM_001363185.1; = p.K674N on NM_052900.3) | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV52299290; called by muse, mutect2, varscan2
- CSTF3 | c.1720G>A p.E574K | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV60614055; called by muse, mutect2, varscan2
- CTNND2 | c.62C>A p.P21H | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV58922179; called by muse, mutect2, varscan2
- CYP4F2 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55621149; called by muse, mutect2, varscan2
- DCSTAMP | c.305G>T p.G102V | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52579832; called by muse, mutect2, varscan2
- DDIAS | c.1034G>C p.R345P | Missense Mutation (SNP) | VAF 38/154 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as COSV61273152; called by muse, mutect2, varscan2
- DGKB | c.733C>A p.H245N | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51814505; called by muse, mutect2, varscan2
- DGKK | c.874C>A p.P292T | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); catalogued as rs782460377, COSV65709255, COSV65709450; called by muse, mutect2, varscan2
- DMTF1 | c.2191C>A p.H731N | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV57539245; called by muse, mutect2, varscan2
- DNAJC13 | c.5000G>T p.G1667V | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53457072; called by muse, mutect2
- DNAJC7 | c.1180G>T p.E394* | Nonsense Mutation (SNP) | VAF 10/85 reads (12%) | catalogued as COSV57270212; called by muse, mutect2, varscan2
- DRD2 | c.1224C>A p.Y408* | Nonsense Mutation (SNP) | VAF 14/113 reads (12%) | catalogued as COSV100669684, COSV60762269; called by muse, mutect2, varscan2
- DST | c.7260T>A p.D2420E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV99749091; called by muse, mutect2, varscan2
- DUSP11 | c.173G>A p.W58* | Nonsense Mutation (SNP) | VAF 18/100 reads (18%) | catalogued as rs1166865806, COSV55596119; called by muse, mutect2, varscan2
- DUSP12 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63411639, COSV63411716; called by muse, mutect2, varscan2
- DYNC1H1 | c.2353G>T p.V785F | Missense Mutation (SNP) | VAF 19/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV64141730; called by muse, mutect2, varscan2
- E2F7 | c.2123G>T p.C708F | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59743131; called by muse, mutect2, varscan2
- ELAVL2 | c.692C>A p.A231D | Missense Mutation (SNP) | VAF 55/276 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV56369783, COSV99807030; called by muse, mutect2, varscan2
- ELSPBP1 | c.71-1G>T p.X24_splice | Splice Site (SNP) | VAF 45/173 reads (26%) | catalogued as COSV60414903; called by muse, mutect2, varscan2
- EPHA3 | c.2662C>A p.L888M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60724340; called by muse, mutect2, varscan2
- FAM155B | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV52937626; called by muse, mutect2, varscan2
- FAM227B | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.127); catalogued as COSV54818286; called by muse, mutect2, varscan2
- FANCB | c.2396C>T p.A799V | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60761540; called by muse, mutect2, varscan2
- FASTKD5 | c.822G>C p.K274N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.123); catalogued as rs780806586, COSV53909194; called by muse, mutect2, varscan2
- FAT2 | c.2903C>A p.A968D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.345); catalogued as COSV55828162; called by muse, mutect2, varscan2
- FCHO1 | c.1835C>A p.S612Y | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs747334107, COSV53183117, COSV99405694; called by muse, mutect2, varscan2
- FCRLA | c.1142C>T p.A381V (on ENST00000367959; = p.A358V on NM_032738.4) | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV52688029; called by muse, mutect2, varscan2
- FLRT3 | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as COSV54044263; called by muse, mutect2, varscan2
- FRMD1 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.506); catalogued as COSV51964602; called by muse, mutect2, varscan2
- FRMD7 | c.1556C>G p.P519R | Missense Mutation (SNP) | VAF 41/255 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.157); catalogued as COSV53748457; called by muse, mutect2, varscan2
- FSCB | c.111C>G p.S37R | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1400520250, COSV61219381; called by muse, mutect2, varscan2
- FUCA2 | c.915G>C p.R305S | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV50020916; called by muse, mutect2
- GAA | c.1216G>T p.D406Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as CM128382, COSV56411719; called by muse, mutect2, varscan2
- GABRA6 | c.1311G>A p.W437* | Nonsense Mutation (SNP) | VAF 12/67 reads (18%) | catalogued as COSV50882370, COSV50892323; called by muse, mutect2, varscan2
- GABRG2 | c.1390T>A p.C464S (on ENST00000361925 / NM_001375343.1; = p.C424S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/144 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV62721862; called by muse, mutect2, varscan2
- GAD2 | c.1072A>G p.K358E | Missense Mutation (SNP) | VAF 23/140 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs1232927880, COSV52166893; called by muse, mutect2, varscan2
- GALNTL5 | c.1258C>A p.L420M | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67181022; called by muse, mutect2, varscan2
- GAREM1 | c.1433G>T p.C478F | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as COSV52515188; called by muse, mutect2, varscan2
- GAS2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.679); catalogued as rs1375035108, COSV53412073; called by muse, mutect2, varscan2
- GASK1B | c.1519A>G p.I507V | Missense Mutation (SNP) | VAF 39/217 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV56711432; called by muse, mutect2, varscan2
- GFRA1 | c.137A>G p.Y46C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV62610110; called by muse, mutect2
- GFRAL | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV61234875; called by muse, mutect2, varscan2
- GJA5 | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.767); catalogued as COSV54783847; called by muse, mutect2, varscan2
- GJA8 | c.357del p.T120Lfs*29 | Frame Shift Del (DEL) | VAF 41/143 reads (29%) | catalogued as COSV99569873; called by mutect2, pindel, varscan2
- GLUD2 | c.1103A>T p.E368V | Missense Mutation (SNP) | VAF 35/267 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV60152956; called by muse, mutect2, varscan2
- GOLGB1 | c.4732G>T p.G1578C | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV61470307; called by muse, mutect2, varscan2
- GPR158 | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 10/266 reads (4%) | catalogued as COSV66280860; called by muse, mutect2
- GPRASP2 | c.772C>A p.H258N | Missense Mutation (SNP) | VAF 37/198 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.676); catalogued as COSV59992361; called by muse, mutect2, varscan2
- GPRASP2 | c.1288A>T p.S430C | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.43); catalogued as COSV59992369; called by muse, mutect2, varscan2
- GPRC6A | c.1538G>A p.R513K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV59955669; called by muse, mutect2, varscan2
- GRHL1 | c.1123G>T p.V375L | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61410567; called by muse, mutect2, varscan2
- GRID1 | c.1783G>T p.A595S | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60049703; called by muse, mutect2, varscan2
- GRIN2B | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.285); catalogued as COSV74207119; called by muse, mutect2, varscan2
- GRIPAP1 | c.2335G>T p.D779Y | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54415742; called by muse, mutect2, varscan2
- GTF2F1 | c.1543C>G p.L515V | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV55531900, COSV55532809; called by muse, mutect2, varscan2
- HDAC11 | c.931A>G p.I311V | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV55474437; called by muse, mutect2, varscan2
- HECTD4 | c.6100A>G p.I2034V | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746497197, COSV66398697; called by muse, mutect2, varscan2
- HERC4 | c.2435T>A p.V812E (on ENST00000395198 / NM_022079.3; = p.V804E on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV53274767; called by muse, mutect2, varscan2
- HOXA13 | c.955T>A p.Y319N | Missense Mutation (SNP) | VAF 19/123 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV56084138; called by muse, mutect2, varscan2
- HRNR | c.2735G>T p.G912V | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.652); catalogued as COSV64262201; called by muse, mutect2, varscan2
- IGSF9B | c.1534G>T p.A512S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV58066353; called by muse, mutect2, varscan2
- IK | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 13/77 reads (17%) | catalogued as COSV70257410, COSV70258172; called by muse, mutect2, varscan2
- IKBKE | c.1859A>G p.H620R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV65623793; called by muse, mutect2
- IL1RAPL2 | c.1192G>T p.D398Y | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV61176410; called by muse, mutect2, varscan2
- IL7R | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV57407391; called by muse, mutect2, varscan2
- IRS4 | c.3676C>A p.P1226T | Missense Mutation (SNP) | VAF 72/349 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.11); catalogued as rs759723131, COSV64535677; called by muse, varscan2
- ISLR2 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV62303581; called by muse, mutect2, varscan2
- ITIH6 | c.2869C>A p.L957M | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV54487929, COSV54493429; called by muse, mutect2, varscan2
- ITPR2 | c.3682G>C p.D1228H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV67275296; called by muse, mutect2
- KCND2 | c.745G>T p.A249S | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV58600544; called by muse, mutect2, varscan2
- KCNF1 | c.807C>A p.S269R | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.151); catalogued as COSV54465425; called by muse, mutect2, varscan2
- KCNH5 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV59775190; called by muse, mutect2, varscan2
- KCNH8 | c.3187T>A p.F1063I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.014); catalogued as rs1270868914, COSV60474783; called by muse, mutect2, varscan2
- KCNK2 | c.620T>C p.V207A (on ENST00000444842 / NM_001017425.3; = p.V192A on NM_014217.4) | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV67209716; called by muse, mutect2
- KIF21B | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59765061; called by muse, mutect2, varscan2
- KIF3A | c.437G>T p.R146L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV101109180, COSV101109330; called by muse, mutect2, varscan2
- KIT | c.2485-1G>A p.X829_splice | Splice Site (SNP) | VAF 19/112 reads (17%) | catalogued as CS022109, COSV55412816; called by muse, mutect2, varscan2
- KLHDC7A | c.1979G>T p.G660V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.147); catalogued as COSV68770815; called by muse, mutect2, varscan2
- KRT12 | c.80T>C p.I27T | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52432266; called by muse, mutect2
- L2HGDH | c.961G>T p.G321C | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55560271; called by muse, mutect2, varscan2
- LAIR2 | c.83G>A p.R28K | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.59); PolyPhen benign (0.247); catalogued as COSV56622906; called by muse, mutect2, varscan2
- LAMA4 | c.3397G>C p.D1133H (on ENST00000230538 / NM_001105206.3; = p.D1126H on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57903131; called by muse, mutect2, varscan2
- LBR | c.220A>T p.R74* | Nonsense Mutation (SNP) | VAF 14/75 reads (19%) | catalogued as COSV55291372; called by muse, mutect2, varscan2
- LCE1F | c.245G>T p.R82L | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.042); catalogued as COSV57668892, COSV57669564; called by muse, mutect2
- LEFTY2 | c.843G>C p.W281C | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64747633; called by muse, mutect2, varscan2
- LILRB1 | c.2045C>A p.P682Q (on ENST00000427581; = p.P631Q on NM_006669.6) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV61121305; called by muse, mutect2, varscan2
- LRRC14B | c.1145T>A p.L382Q | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as COSV52054095; called by muse, mutect2, varscan2
- LRRC15 | c.326C>A p.A109D | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV61651375; called by muse, mutect2
- LUZP4 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | catalogued as rs782503093, CM134624, COSV64218880; called by muse, mutect2, varscan2
- LYAR | c.901G>T p.D301Y | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.168); catalogued as COSV58643912; called by muse, mutect2, varscan2
- MAGEA10 | c.580G>T p.V194L | Missense Mutation (SNP) | VAF 20/126 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs1355409389, COSV54885644; called by muse, mutect2, varscan2
- MAGEA6 | c.250T>G p.Y84D | Missense Mutation (SNP) | VAF 20/105 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61449402; called by mutect2, varscan2
- MAGEA8 | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV54064911; called by muse, mutect2, varscan2
- MAGEB16 | c.374T>A p.L125Q | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67874502; called by muse, mutect2, varscan2
- MAGEB6B | c.821G>A p.G274E | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.681); catalogued as rs1248193622; called by muse, mutect2
- MAGT1 | c.449G>T p.R150L (on ENST00000618282 / NM_001367916.1; = p.R182L on NM_032121.5) | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV63782990; called by muse, mutect2
- MAN2A1 | c.35G>T p.S12I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as COSV54857616; called by muse, mutect2, varscan2
- MAP4K2 | c.1595G>T p.W532L | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53647937; called by muse, mutect2, varscan2
- MAP4K3 | c.1984G>T p.V662L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as COSV55717566; called by muse, varscan2
- MARCHF6 | c.1471G>T p.V491F | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56886397; called by muse, mutect2, varscan2
- MARK1 | c.849C>G p.D283E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV65070890; called by muse, mutect2
- MECP2 | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 86/576 reads (15%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.972); catalogued as rs61753980, CM011406, COSV57656529; called by muse, varscan2
- MED12 | c.3602C>A p.S1201Y | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.547); catalogued as COSV100375141; called by muse, mutect2
- MLC1 | c.416C>G p.A139G | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.994); catalogued as COSV61118657; called by muse, mutect2, varscan2
- MOGS | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 28/222 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.358); catalogued as rs755702841, COSV51969611; called by muse, mutect2, varscan2
- MORC4 | c.1756C>G p.P586A | Missense Mutation (SNP) | VAF 31/205 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as COSV55246116; called by muse, mutect2, varscan2
- MPO | c.1937G>T p.G646V | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51862013; called by muse, mutect2, varscan2
- MRAP2 | c.559C>A p.P187T | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1465005376, COSV57634628; called by muse, mutect2, varscan2
- MSH3 | c.2671G>T p.V891L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as COSV54152421, COSV54162128; called by muse, mutect2
- MTR | c.2124T>G p.I708M | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63966181; called by muse, mutect2, varscan2
- MTUS2 | c.2431A>T p.S811C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as COSV70921730; called by muse, mutect2, varscan2
- MXRA5 | c.6853G>T p.V2285L | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV54248231; called by muse, mutect2, varscan2
- MXRA5 | c.4448C>A p.P1483H | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.431); catalogued as COSV54248251; called by muse, mutect2, varscan2
- MYCT1 | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV65891915, COSV65891920; called by muse, mutect2, varscan2
- MYH13 | c.1754C>G p.A585G | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV52841029; called by muse, mutect2, varscan2
- MYH8 | c.5514G>T p.E1838D | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as COSV67971407; called by muse, mutect2, varscan2
- MYL1 | c.242C>A p.A81D | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100498692, COSV58976696; called by muse, mutect2
- MYO16 | c.3140C>T p.S1047L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as COSV100697418, COSV62760038; called by muse, mutect2
- MYO7B | c.349G>T p.E117* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as rs1323471040, COSV67351421; called by muse, mutect2
- MYRIP | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV56879791; called by muse, mutect2, varscan2
- NALCN | c.4111A>G p.N1371D | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51961520; called by muse, mutect2
- NCKAP5 | c.2393A>G p.Q798R | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.083); catalogued as COSV58471300; called by muse, mutect2, varscan2
- NCOA2 | c.1633G>T p.G545W | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71763651, COSV71764814; called by muse, mutect2, varscan2
- NDUFAF1 | c.706A>G p.M236V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.021); catalogued as rs1208693484, COSV52976282; called by muse, mutect2, varscan2
- NDUFV3 | c.49-2A>T p.X17_splice | Splice Site (SNP) | VAF 6/77 reads (8%) | catalogued as COSV61088490; called by muse, mutect2
- NID2 | c.3295C>A p.P1099T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV53502079; called by muse, mutect2, varscan2
- NIN | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV55404487; called by muse, mutect2, varscan2
- NLGN4X | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52034145; called by muse, mutect2, varscan2
- NLRP4 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0.088); catalogued as COSV56712728, COSV56721965; called by muse, mutect2, varscan2
- NOL4 | c.1174G>C p.D392H | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as COSV52359882; called by muse, mutect2, varscan2
- NPAS2 | c.1187A>T p.D396V | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV59561635; called by muse, mutect2, varscan2
- NPY1R | c.74T>C p.L25P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV56716140; called by muse, mutect2, varscan2
- NR0B1 | c.757G>T p.V253L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as COSV66764718; called by muse, mutect2, varscan2
- NRXN1 | c.3020C>T p.T1007I | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); catalogued as COSV58487325, COSV58492081; called by muse, mutect2, varscan2
- NRXN2 | c.3847+2T>C p.X1283_splice | Splice Site (SNP) | VAF 15/54 reads (28%) | catalogued as COSV55462004; called by muse, mutect2, varscan2
- NXPE1 | c.1556T>A p.M519K (on ENST00000424269; = p.M377K on NM_152315.5) | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV52632707; called by muse, mutect2, varscan2
- OLFM4 | c.1096A>T p.N366Y | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV54580026; called by muse, mutect2, varscan2
- OPN4 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54119260; called by muse, mutect2, varscan2
- OR10AG1 | c.337C>G p.R113G | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV56634488; called by muse, mutect2, varscan2
- OR10K2 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as rs1304069468, COSV59222572; called by muse, mutect2, varscan2
- OR10R2 | c.96C>A p.F32L | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63769445, COSV63769564; called by muse, mutect2, varscan2
- OR11L1 | c.901G>T p.V301F | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV63315593; called by muse, mutect2, varscan2
- OR2D2 | c.378C>G p.I126M | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs747378505, COSV55058125; called by muse, mutect2, varscan2
- OR2T8 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 71/240 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.613); catalogued as COSV60664653; called by muse, mutect2, varscan2
- OR2W3 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 25/171 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as rs774045260, COSV64457885; called by muse, mutect2, varscan2
- OR4C46 | c.431G>T p.G144V | Missense Mutation (SNP) | VAF 25/189 reads (13%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.098); catalogued as rs376738452, COSV60220154; called by muse, mutect2, varscan2
- OR4D11 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.014); catalogued as rs114830141; called by muse, mutect2, varscan2
- OR4E2 | c.608G>T p.S203I | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV57732245; called by muse, mutect2, varscan2
- OR4Q3 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV59180143; called by muse, mutect2
- OR51E2 | c.875G>T p.G292V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV67807863, COSV67808620; called by muse, mutect2, varscan2
- OR5D13 | c.214G>A p.D72N | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62335118; called by muse, mutect2, varscan2
- OR5J2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT tolerated (0.82); PolyPhen benign (0.003); catalogued as rs573804726, COSV56621378, COSV56622916; called by muse, mutect2, varscan2
- OR6B1 | c.769T>C p.Y257H | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV68770597; called by muse, mutect2
- OR6M1 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV58434736; called by muse, mutect2, varscan2
- OR6V1 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs755314327, COSV69237652; called by muse, mutect2, varscan2
- OR8H2 | c.164A>T p.Q55L | Missense Mutation (SNP) | VAF 64/361 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV57947212; called by muse, mutect2, varscan2
- OR9Q1 | c.208G>T p.D70Y | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59046355; called by muse, mutect2, varscan2
- OTX1 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.414); catalogued as COSV56996008; called by muse, mutect2, varscan2
- OTX2 | c.723G>T p.Q241H (on ENST00000408990 / NM_172337.3; = p.Q249H on NM_021728.4) | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as COSV59767292, COSV59767411; called by muse, mutect2, varscan2
- P2RY10 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as COSV50685195; called by muse, mutect2
- PCDH1 | c.2648A>G p.K883R | Missense Mutation (SNP) | VAF 61/312 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.791); catalogued as COSV54618806; called by muse, mutect2, varscan2
- PCDH15 | c.436A>T p.T146S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as rs538604534, COSV57382583; called by muse, varscan2
- PCDH17 | c.977T>A p.L326Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.192); catalogued as COSV64978466; called by muse, mutect2, varscan2
- PCDHA2 | c.1748G>A p.W583* | Nonsense Mutation (SNP) | VAF 15/136 reads (11%) | catalogued as rs1218240596, COSV65370671; called by muse, mutect2, varscan2
- PCDHA5 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.07); catalogued as rs1264237744, COSV100972504, COSV65357081; called by muse, mutect2, varscan2
- PCDHB10 | c.1877C>T p.T626I | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV53383178; called by muse, mutect2, varscan2
- PCDHB10 | c.2253C>A p.Y751* | Nonsense Mutation (SNP) | VAF 24/213 reads (11%) | catalogued as rs199821453, COSV53379701; called by muse, mutect2, varscan2
- PCDHB3 | c.858A>T p.E286D | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.065); catalogued as COSV50624535; called by muse, mutect2, varscan2
- PCDHB4 | c.2336G>T p.G779V | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV52026470; called by muse, varscan2
- PCDHGA11 | c.258C>G p.I86M | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.482); catalogued as COSV54019669; called by muse, mutect2, varscan2
- PCDHGA3 | c.1654G>T p.V552L | Missense Mutation (SNP) | VAF 57/286 reads (20%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.2); catalogued as rs2879227, COSV53917570, COSV54011719; called by muse, mutect2, varscan2
- PCDHGB1 | c.2330T>A p.L777Q | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV54019649; called by muse, mutect2, varscan2
- PCLO | c.11642C>G p.P3881R | Missense Mutation (SNP) | VAF 68/483 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV61620733, COSV61661612; called by muse, mutect2, varscan2
- PDE9A | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.424); catalogued as COSV52330830, COSV99372284; called by muse, mutect2, varscan2
- PDK3 | c.1177A>T p.S393C | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV64794339; called by muse, mutect2
- PGK1 | c.1015C>A p.P339T | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59372261; called by muse, mutect2
- PIEZO2 | c.6707T>G p.M2236R | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53293402; called by muse, varscan2
- PITX2 | c.566T>A p.L189Q (on ENST00000354925 / NM_001204397.1; = p.L196Q on NM_000325.6) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60742161; called by muse, mutect2, varscan2
- PLXNA4 | c.655C>A p.H219N | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.438); catalogued as COSV58156127; called by muse, mutect2, varscan2
- PNMA3 | c.632G>T p.G211V | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64722728; called by muse, mutect2, varscan2
- PNMA5 | c.825C>A p.H275Q | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62626212; called by muse, mutect2, varscan2
- PODXL2 | c.754A>G p.T252A | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs771599815, COSV61066421; called by muse, mutect2, varscan2
- POLA2 | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.021); catalogued as rs1455088841, COSV55485871; called by muse, mutect2, varscan2
- PPP1R12B | c.276G>T p.L92F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV61122991; called by muse, mutect2, varscan2
- PPP1R3A | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV52891785; called by muse, mutect2, varscan2
- PREB | c.682G>C p.V228L | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53208046; called by muse, mutect2, varscan2
- PRKCQ | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.058); catalogued as rs549529749, COSV54115950, COSV54118123; called by muse, mutect2, varscan2
- PROS1 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101260481, COSV67776910; called by muse, mutect2, varscan2
- PRRC2C | c.1978G>A p.A660T (on ENST00000367742; = p.A658T on NM_015172.4) | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV58904085; called by muse, mutect2, varscan2
- PRUNE1 | c.1045A>T p.K349* | Nonsense Mutation (SNP) | VAF 75/260 reads (29%) | catalogued as COSV54848691; called by muse, mutect2, varscan2
- PTPRD | c.2368C>A p.L790I | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV61977427; called by muse, mutect2, varscan2
- QSER1 | c.453G>T p.L151F (on ENST00000399302; = p.L280F on NM_001076786.3) | Missense Mutation (SNP) | VAF 26/160 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67901685; called by muse, mutect2, varscan2
- RAPGEF2 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52426914; called by muse, mutect2, varscan2
- RBM15 | c.1187G>T p.R396L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63924358; called by muse, mutect2, varscan2
- RBM33 | c.2815G>T p.E939* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV56636765; called by muse, mutect2, varscan2
- RBM41 | c.1208C>A p.A403D | Missense Mutation (SNP) | VAF 37/279 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV52564986; called by muse, mutect2, varscan2
- RBSN | c.1262G>T p.R421L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs139040870; called by muse, mutect2, varscan2
- RELN | c.8159A>T p.E2720V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); catalogued as COSV59030444; called by muse, mutect2, varscan2
- REPS2 | c.703C>A p.Q235K | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.118); catalogued as COSV58187476; called by muse, mutect2, varscan2
- RETSAT | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV55528380, COSV55528581; called by muse, mutect2, varscan2
- RHAG | c.835G>T p.G279* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as COSV57706062; called by muse, mutect2, varscan2
- RIMS1 | c.2324G>A p.G775E | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53457267; called by muse, mutect2
- RIMS2 | c.4126G>T p.E1376* (on ENST00000666250 / NM_001348490.2; = p.E947* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 34/166 reads (20%) | catalogued as COSV51718756, COSV99211456; called by muse, mutect2, varscan2
- RMC1 | c.1540C>G p.L514V | Missense Mutation (SNP) | VAF 71/459 reads (15%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.473); catalogued as rs1404640755, COSV52574181; called by muse, mutect2, varscan2
- RNMT | c.384A>T p.K128N | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as COSV51089937; called by muse, mutect2, varscan2
- ROR2 | c.2068C>A p.L690M | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV65222720; called by muse, mutect2, varscan2
- RP1L1 | c.4945G>T p.E1649* | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV66759557; called by muse, mutect2, varscan2
- RTL3 | c.325C>A p.P109T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.108); catalogued as rs1473456843, COSV58183832; called by muse, mutect2, varscan2
- RTL5 | c.107T>A p.L36H | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65454819; called by muse, mutect2, varscan2
- RTTN | c.2365G>T p.A789S | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99730467; called by muse, mutect2
- RTTN | c.611G>T p.W204L | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as COSV99733598; called by muse, mutect2
- RYR2 | c.14672G>T p.C4891F | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV63710201; called by muse, mutect2, varscan2
- SALL1 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV51763798; called by muse, varscan2
- SDCBP2 | c.207G>C p.Q69H | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV60590798; called by muse, mutect2, varscan2
- SEMA6A | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1256707797, COSV104378646, COSV56714524; called by muse, mutect2, varscan2
- SEMA6D | c.61G>C p.V21L | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV60383039; called by muse, mutect2, varscan2
- SERPINA7 | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 59/420 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.095); catalogued as COSV100568247, COSV59667170; called by muse, mutect2, varscan2
- SH3BP5L | c.1085G>T p.S362I | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV63539826; called by muse, mutect2
- SH3TC2 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60467360; called by muse, mutect2, varscan2
- SHISAL2A | c.380T>G p.V127G | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.319); catalogued as COSV68980201; called by muse, mutect2, varscan2
- SHKBP1 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52543246; called by muse, mutect2, varscan2
- SHROOM4 | c.1467C>A p.H489Q | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV56796423; called by muse, mutect2, varscan2
- SLC10A2 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs371460461, COSV55361342, COSV99808103; called by muse, mutect2, varscan2
- SLC10A3 | c.623G>T p.G208V | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54837356; called by muse, mutect2, varscan2
- SLC35F3 | c.184C>T p.Q62* (on ENST00000366617 / NM_001300845.1; = p.Q131* on NM_173508.4) | Nonsense Mutation (SNP) | VAF 18/139 reads (13%) | catalogued as COSV64021432; called by muse, mutect2, varscan2
- SLC7A3 | c.1710T>A p.F570L | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); catalogued as COSV53229142; called by muse, mutect2, varscan2
- SLC8A1 | c.928C>A p.L310M | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.348); catalogued as COSV60494704; called by muse, mutect2, varscan2
- SMCHD1 | c.4475T>C p.V1492A | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0.108); catalogued as rs201217574, COSV55266855; called by muse, mutect2, varscan2
- SNCAIP | c.1730C>A p.P577Q | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.143); catalogued as COSV54420138; called by muse, mutect2, varscan2
- SNTG1 | c.161G>T p.G54V | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.726); catalogued as COSV99380042; called by muse, mutect2, varscan2
- SORBS2 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs767319986, COSV53013224; called by muse, mutect2, varscan2
- SORD | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51044898; called by muse, mutect2, varscan2
- SOX3 | c.382A>T p.S128C | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.219); catalogued as COSV65168616; called by mutect2, varscan2
- SPECC1 | c.988G>T p.D330Y | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54956730, COSV54961422, COSV54965216; called by muse, mutect2
- SPRED2 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 35/177 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs375121510; called by muse, mutect2, varscan2
- SPTA1 | c.2758C>A p.P920T | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV63758428; called by muse, mutect2, varscan2
- SPTA1 | c.1056G>T p.W352C | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933962; called by muse, mutect2, varscan2
- SPTA1 | c.1055G>T p.W352L | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933963; called by muse, mutect2, varscan2
- ST8SIA3 | c.659A>T p.N220I | Missense Mutation (SNP) | VAF 12/70 reads (17%) | PolyPhen probably damaging (0.942); catalogued as COSV60655168; called by muse, mutect2, varscan2
- STAG2 | c.1318A>G p.R440G | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.179); catalogued as COSV54370997; called by muse, mutect2
- STXBP5 | c.3319G>T p.A1107S (on ENST00000321680 / NM_001127715.2; = p.A1071S on NM_139244.4) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.989); catalogued as COSV51657549; called by muse, mutect2, varscan2
- SUN1 | c.2134C>T p.Q712* (on ENST00000405266 / NM_001367651.1; = p.Q592* on NM_025154.6 and 13 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/199 reads (18%) | catalogued as COSV67451744; called by muse, mutect2, varscan2
- SYNE3 | c.2654A>G p.Y885C | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62082229; called by muse, mutect2, varscan2
- SYT7 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55658944; called by muse, mutect2, varscan2
- SYT9 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.76); PolyPhen benign (0.086); catalogued as COSV59616608; called by muse, mutect2, varscan2
- TACC2 | c.6206G>T p.R2069L (on ENST00000334433; = p.R147L on NM_006997.4) | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53288679; called by muse, mutect2, varscan2
- TACC3 | c.1591G>A p.V531I | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as COSV57607607; called by muse, mutect2, varscan2
- TAS2R60 | c.534G>T p.W178C | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60331407, COSV60331929; called by muse, mutect2, varscan2
- TAT | c.998G>T p.R333L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.265); catalogued as COSV63532774, COSV63533443; called by muse, mutect2, varscan2
- TENM1 | c.1755G>T p.K585N | Missense Mutation (SNP) | VAF 74/375 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV64430251, COSV64441380; called by muse, mutect2, varscan2
- TESPA1 | c.1087T>C p.C363R (on ENST00000316577 / NM_001098815.3; = p.C225R on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV57260987; called by muse, mutect2, varscan2
- TEX55 | c.696_743del p.S237_Q252del | In Frame Del (DEL) | VAF 18/132 reads (14%) | catalogued as rs753960997; called by muse*, mutect2, pindel
- TG | c.4684G>T p.D1562Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV55092020; called by muse, mutect2, varscan2
- TGFBI | c.680G>C p.G227A | Missense Mutation (SNP) | VAF 30/224 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100526422, COSV59354038; called by muse, mutect2, varscan2
- TGIF2LX | c.566C>G p.P189R | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.88); catalogued as COSV52213338, COSV52215060; called by muse, mutect2, varscan2
- TLL1 | c.2497G>C p.E833Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as COSV50317185; called by muse, mutect2
- TMEM145 | c.987G>C p.W329C | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV56627557; called by muse, mutect2, varscan2
- TMEM179B | c.532G>C p.V178L | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53670815; called by muse, mutect2, varscan2
- TMPRSS11B | c.8+2T>G p.X3_splice | Splice Site (SNP) | VAF 22/100 reads (22%) | catalogued as COSV100219150; called by muse, mutect2, varscan2
- TMPRSS11B | c.8+1G>A p.X3_splice | Splice Site (SNP) | VAF 22/98 reads (22%) | catalogued as rs1434689644, COSV100219151; called by muse, mutect2, varscan2
- TMPRSS11D | c.1196C>A p.P399Q | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52225809; called by muse, mutect2, varscan2
- TNNI3 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV52571137; called by muse, varscan2
- TPPP | c.142C>T p.L48F | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV62193497; called by muse, mutect2, varscan2
- TRH | c.319del p.A107Lfs*23 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | catalogued as rs770451471, COSV57014685; called by mutect2, varscan2
- TRIM48 | c.354G>A p.M118I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1295582029, COSV70162220; called by muse, mutect2
- TRIM56 | c.1906G>T p.A636S | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.968); catalogued as COSV60161186; called by muse, mutect2, varscan2
- TRPC3 | c.1568G>T p.W523L (on ENST00000379645 / NM_001366479.2; = p.W450L on NM_003305.2) | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.58); catalogued as COSV53380507; called by muse, mutect2
- TTN | c.56201C>G p.P18734R (on ENST00000591111; = p.P11310R on NM_003319.4) | Missense Mutation (SNP) | VAF 21/142 reads (15%) | PolyPhen probably damaging (0.999); catalogued as COSV60302638; called by muse, mutect2, varscan2
- UBXN2A | c.403G>T p.G135* | Nonsense Mutation (SNP) | VAF 13/45 reads (29%) | catalogued as COSV58337730; called by muse, mutect2, varscan2
- UCK2 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as rs1242029217, COSV100903004, COSV63316731; called by muse, mutect2, varscan2
- UGT2B4 | c.707A>T p.Y236F | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as COSV59320041; called by muse, mutect2, varscan2
- UNC5C | c.688del p.R230Dfs*27 | Frame Shift Del (DEL) | VAF 33/191 reads (17%) | catalogued as COSV71661898; called by mutect2, pindel, varscan2
- URGCP | c.1389C>A p.D463E (on ENST00000453200 / NM_001077663.3; = p.D454E on NM_017920.4) | Missense Mutation (SNP) | VAF 36/195 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV56250777, COSV56252188; called by muse, mutect2, varscan2
- USH2A | c.4217C>A p.S1406* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as rs1308702971, COSV56425599; called by muse, mutect2, varscan2
- USP11 | c.2891G>C p.*964Sext*40 (on ENST00000218348; = p.*921Sext*40 on NM_001371072.1) | Nonstop Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV54475762; called by muse, varscan2
- USP49 | c.778A>T p.N260Y | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51900752; called by muse, mutect2
- UST | c.693G>T p.E231D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as COSV66550051, COSV99054932; called by muse, mutect2, varscan2
- UTS2R | c.482G>T p.R161L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV100493250; called by muse, mutect2
- VNN2 | c.1200G>T p.Q400H | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58474011; called by muse, mutect2, varscan2
- VWF | c.1060G>T p.G354* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as COSV54632567, COSV99779710; called by muse, mutect2, varscan2
- WNK3 | c.2822T>A p.V941E | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.188); catalogued as COSV63615691; called by muse, mutect2, varscan2
- WNT7A | c.492G>T p.K164N | Missense Mutation (SNP) | VAF 15/213 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.333); catalogued as COSV53201749; called by muse, mutect2
- YWHAG | c.485A>T p.K162I | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.784); catalogued as COSV56902318; called by muse, mutect2, varscan2
- YY2 | c.497C>A p.T166K | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs891364185, COSV63412345; called by muse, mutect2, varscan2
- ZADH2 | c.943G>T p.A315S | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV59269496; called by muse, mutect2, varscan2
- ZCCHC12 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59570916; called by muse, mutect2, varscan2
- ZDBF2 | c.5603T>C p.V1868A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV65629544; called by mutect2, varscan2
- ZDHHC15 | c.259-2A>T p.X87_splice | Splice Site (SNP) | VAF 12/48 reads (25%) | catalogued as COSV64903551; called by muse, mutect2, varscan2
- ZIC4 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67173898; called by muse, mutect2, varscan2
- ZIC4 | c.634G>T p.G212W | Missense Mutation (SNP) | VAF 28/156 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67173906; called by muse, mutect2, varscan2
- ZMYM2 | c.3609G>T p.R1203S | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.023); catalogued as COSV67037190; called by muse, mutect2, varscan2
- ZNF107 | c.2176G>T p.G726C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100788121; called by muse, mutect2, varscan2
- ZNF34 | c.656C>T p.S219L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV58638633, COSV58641124; called by muse, mutect2, varscan2
- ZNF417 | c.224G>T p.R75I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.169); catalogued as COSV100364009; called by muse, mutect2, varscan2
- ZNF512B | c.1503G>T p.Q501H | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.897); catalogued as COSV99410983; called by muse, varscan2
- ZNF592 | c.3766C>G p.Q1256E | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.018); catalogued as COSV100245728, COSV55439286; called by muse, mutect2
- ZNF799 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 20/101 reads (20%) | catalogued as COSV70123369; called by muse, mutect2, varscan2
- ZNF804A | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 4/60 reads (7%) | catalogued as COSV100167980, COSV56468460; called by muse, mutect2
- ZNF91 | c.869G>T p.G290V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV56091761; called by muse, mutect2, varscan2
- ZNF98 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100757219; called by mutect2, varscan2
- ZXDA | c.840G>T p.K280N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV62388778; called by muse, mutect2
- ADNP2 | c.1710dup p.V571Cfs*147 | Frame Shift Ins (INS) | VAF 18/110 reads (16%) | called by mutect2, pindel, varscan2
- AMER1 | c.1395del p.N466Ifs*75 | Frame Shift Del (DEL) | VAF 10/81 reads (12%) | called by pindel, varscan2
- C9orf131 | c.1252_1263del p.E418_G421del | In Frame Del (DEL) | VAF 13/117 reads (11%) | called by mutect2, pindel
- CCDC142 | c.745del p.S249Vfs*12 | Frame Shift Del (DEL) | VAF 15/70 reads (21%) | called by mutect2, pindel, varscan2
- DNAH9 | c.2314del p.L772Sfs*8 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- ELMO1 | c.134dup p.N45Kfs*3 | Frame Shift Ins (INS) | VAF 7/41 reads (17%) | called by mutect2, pindel, varscan2
- FNDC3B | c.1283G>T p.C428F | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.415); called by muse, mutect2
- FUBP3 | c.199del p.Q67Sfs*2 | Frame Shift Del (DEL) | VAF 21/77 reads (27%) | called by mutect2, pindel, varscan2
- KIFC3 | c.1192_1194delinsTA p.E398* | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | called by pindel, varscan2*
- KRTAP5-10 | c.243dup p.G82Rfs*65 | Frame Shift Ins (INS) | VAF 28/242 reads (12%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.224C>A p.A75E | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- MYOM2 | c.2885G>T p.G962V | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- NOTCH1 | c.2072del p.G691Afs*81 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- OR2A12 | c.284del p.P95Lfs*18 | Frame Shift Del (DEL) | VAF 18/98 reads (18%) | called by mutect2, pindel, varscan2
- PCDH10 | c.1726_1744del p.A576Tfs*45 | Frame Shift Del (DEL) | VAF 11/100 reads (11%) | called by mutect2, pindel
- PRB4 | c.507del p.G170Efs*87 | Frame Shift Del (DEL) | VAF 71/444 reads (16%) | called by mutect2, pindel, varscan2
- SAMD7 | c.411_418del p.A138Wfs*9 | Frame Shift Del (DEL) | VAF 8/84 reads (10%) | called by mutect2, pindel
- SCN2B | c.463del p.D155Tfs*6 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- SMOC1 | c.758dup p.G254Wfs*5 | Frame Shift Ins (INS) | VAF 26/143 reads (18%) | called by mutect2, pindel, varscan2
- TAAR6 | c.303del p.R102Gfs*83 | Frame Shift Del (DEL) | VAF 31/154 reads (20%) | called by mutect2, pindel, varscan2
- TLL1 | c.1451del p.P484Rfs*2 | Frame Shift Del (DEL) | VAF 13/114 reads (11%) | called by pindel, varscan2*
- TTK | c.1814dup p.N606Kfs*3 | Frame Shift Ins (INS) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- ZCRB1 | c.61del p.L21* | Frame Shift Del (DEL) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- ACOT11 | c.519G>A p.E173= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs1224358659, COSV59351481; called by muse, mutect2, varscan2
- ACOXL | c.1617G>T p.T539= (on ENST00000389811 / NM_001371254.1; = p.T509= on NM_001142807.4) | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV67738157; called by muse, mutect2
- ACSL1 | c.885C>T p.S295= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs943916379, COSV55666197; called by muse, mutect2, varscan2
- ACTBL2 | c.715C>A p.R239= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as rs762977415, COSV70661154, COSV70661702; called by muse, mutect2, varscan2
- ADAMTS8 | c.1992C>A p.A664= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as COSV57297151; called by muse, mutect2, varscan2
- ADH1B | c.1098G>A p.G366= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV59298214; called by muse, mutect2, varscan2
- AHNAK2 | c.4602G>A p.G1534= | Silent (SNP) | VAF 60/338 reads (18%) | catalogued as COSV60928609; called by muse, mutect2
- AIRE | c.990C>A p.I330= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1036633160, COSV52394170, COSV52396753; called by muse, mutect2, varscan2
- AZU1 | c.738G>A p.P246= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as rs200997500, COSV52142457; called by muse, mutect2, varscan2
- BMP3 | c.786C>T p.H262= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as COSV51094027; called by muse, mutect2, varscan2
- C11orf87 | c.333T>A p.G111= | Silent (SNP) | VAF 22/118 reads (19%) | catalogued as COSV59356117, COSV59358293; called by muse, mutect2, varscan2
- C6orf118 | c.537G>T p.L179= | Silent (SNP) | VAF 22/93 reads (24%) | catalogued as COSV57818491; called by muse, mutect2, varscan2
- CCDC185 | c.1017G>T p.V339= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1344361201, COSV64821765; called by muse, mutect2
- CDH12 | c.2136C>T p.D712= | Silent (SNP) | VAF 16/85 reads (19%) | catalogued as COSV66442488; called by muse, mutect2, varscan2
- CHRM3 | c.1035C>T p.S345= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs761812337, COSV55089422, COSV55101595; called by muse, mutect2, varscan2
- COP1 | c.438A>G p.A146= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as COSV58174833; called by muse, mutect2, varscan2
- CRB1 | c.2520G>A p.E840= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100957966, COSV66333104; called by muse, mutect2, varscan2
- CREBZF | c.243G>A p.E81= | Silent (SNP) | VAF 27/144 reads (19%) | catalogued as COSV52630624; called by muse, mutect2, varscan2
- CTNND2 | c.2187C>A p.A729= | Silent (SNP) | VAF 20/152 reads (13%) | catalogued as COSV58922164; called by muse, mutect2
- CUL7 | c.198G>T p.L66= | Silent (SNP) | VAF 13/129 reads (10%) | catalogued as COSV54821387; called by muse, mutect2
- CXorf56 | c.114C>A p.V38= | Silent (SNP) | VAF 23/189 reads (12%) | catalogued as rs772616758, COSV57439220; called by muse, mutect2, varscan2
- CYP11B2 | c.1035G>C p.L345= | Silent (SNP) | VAF 27/158 reads (17%) | catalogued as rs780878883, COSV59997631; called by muse, mutect2, varscan2
- DCC | c.823C>A p.R275= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs754914260, CM145915, COSV100502237, COSV59130602; called by muse, mutect2, varscan2
- DSG3 | c.2787T>C p.G929= | Silent (SNP) | VAF 21/120 reads (18%) | catalogued as COSV57129256; called by muse, mutect2, varscan2
- DTX2 | c.288G>A p.R96= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV56864690; called by muse, mutect2, varscan2
- DUSP15 | c.312G>T p.T104= (on ENST00000278979 / NM_001320479.1; = p.T107= on NM_080611.4) | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99639329; called by muse, mutect2, varscan2
- EIF4A2 | c.465T>C p.I155= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV56218481; called by muse, mutect2
- EPHA10 | c.540C>A p.I180= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV60405277; called by muse, mutect2, varscan2
- EPHB6 | c.373C>A p.R125= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as rs761261838, COSV67417054, COSV67420591; called by muse, mutect2, varscan2
- ERBB4 | c.1659G>T p.V553= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV53580121; called by muse, mutect2, varscan2
- ERI3 | c.798G>A p.A266= | Silent (SNP) | VAF 10/63 reads (16%) | catalogued as rs762951528, COSV64833402; called by muse, mutect2, varscan2
- FAT2 | c.1707T>C p.C569= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs778654589, COSV55828175; called by muse, mutect2
- FBN2 | c.8658G>T p.L2886= | Silent (SNP) | VAF 24/158 reads (15%) | catalogued as COSV52541686; called by muse, mutect2, varscan2
- FCHO1 | c.1836C>A p.S612= | Silent (SNP) | VAF 32/177 reads (18%) | catalogued as COSV99405700; called by muse, mutect2, varscan2
- FCRL1 | c.1023T>C p.D341= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV63827123; called by muse, mutect2, varscan2
- FTMT | c.636G>T p.V212= | Silent (SNP) | VAF 31/215 reads (14%) | catalogued as COSV58421303; called by muse, mutect2, varscan2
- FZD10 | c.1023G>A p.K341= | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs1259049078, COSV57474583, COSV57475612; called by muse, mutect2, varscan2
- GCLC | c.393A>G p.L131= (on ENST00000643939; = p.L135= on NM_001498.4) | Silent (SNP) | VAF 16/206 reads (8%) | catalogued as COSV57597609; called by muse, mutect2
- GDI2 | c.999C>T p.Y333= | Silent (SNP) | VAF 10/84 reads (12%) | catalogued as rs774905963, COSV60169307; called by mutect2, varscan2
- GPM6A | c.666G>A p.G222= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as rs1240819970, COSV54558744; called by muse, mutect2, varscan2
- GPR101 | c.1194T>C p.A398= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV53240182; called by muse, mutect2, varscan2
- GRM8 | c.2673C>A p.T891= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as rs1191821091, COSV58862247; called by muse, mutect2, varscan2
- GRPR | c.459C>A p.A153= | Silent (SNP) | VAF 22/124 reads (18%) | catalogued as COSV66670170; called by muse, mutect2, varscan2
- GTF2E1 | c.525A>G p.T175= | Silent (SNP) | VAF 31/266 reads (12%) | catalogued as COSV52204723; called by muse, mutect2, varscan2
- HCN1 | c.2487A>G p.A829= | Silent (SNP) | VAF 13/64 reads (20%) | catalogued as COSV57534281; called by muse, mutect2, varscan2
- HRNR | c.630T>C p.S210= | Silent (SNP) | VAF 34/266 reads (13%) | catalogued as rs372474699, COSV64262205; called by muse, mutect2, varscan2
- IGF2R | c.2097A>G p.S699= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as rs753133503, COSV63632348; called by muse, mutect2, varscan2
- ITIH5 | c.1278C>A p.A426= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV53672639, COSV99903206; called by muse, mutect2
- KCNA5 | c.1248C>T p.H416= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV52908288; called by muse, mutect2, varscan2
- KCNC1 | c.876G>A p.E292= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as COSV56398023; called by muse, mutect2, varscan2
- KIF19 | c.1125C>A p.I375= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as COSV63430464; called by muse, mutect2, varscan2
- KYNU | c.562C>A p.R188= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV51590896; called by muse, mutect2, varscan2
- LRRC30 | c.528G>T p.A176= | Silent (SNP) | VAF 25/150 reads (17%) | catalogued as COSV67301257, COSV67302230; called by muse, mutect2, varscan2
- MAGEB6 | c.873C>T p.L291= | Silent (SNP) | VAF 21/308 reads (7%) | catalogued as COSV66872328, COSV66872976; called by muse, mutect2
- MAGEE2 | c.669G>A p.R223= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as rs367730676, COSV64898027; called by muse, mutect2, varscan2
- MAP2 | c.3747C>G p.L1249= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV52305791; called by muse, mutect2, varscan2
- MCM5 | c.1155A>T p.T385= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV53346474; called by muse, mutect2, varscan2
- MRPL16 | c.708C>A p.T236= | Silent (SNP) | VAF 47/233 reads (20%) | catalogued as COSV55700798; called by muse, mutect2, varscan2
- MRPL22 | c.9G>T p.A3= | Silent (SNP) | VAF 24/161 reads (15%) | catalogued as COSV53564320; called by muse, mutect2, varscan2
- MUC2 | c.2823C>T p.S941= | Silent (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- MYOM2 | c.2886G>T p.G962= | Silent (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- MYT1L | c.15C>G p.T5= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV67730958; called by muse, mutect2, varscan2
- NLRP10 | c.321C>A p.R107= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV60782344; called by muse, mutect2, varscan2
- NLRP12 | c.2121G>T p.A707= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV60753895; called by muse, mutect2, varscan2
- NPBWR1 | c.558C>A p.R186= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1190694492, COSV58697600; called by muse, mutect2
- NPY5R | c.63C>A p.A21= | Silent (SNP) | VAF 14/63 reads (22%) | catalogued as COSV58453693; called by muse, mutect2, varscan2
- NR5A1 | c.918G>A p.L306= | Silent (SNP) | VAF 14/36 reads (39%) | catalogued as rs757183764, COSV101007747, COSV65295565; called by muse, mutect2, varscan2
- OOSP2 | c.375T>A p.S125= | Silent (SNP) | VAF 25/124 reads (20%) | catalogued as COSV53929937; called by muse, mutect2, varscan2
- OR10AG1 | c.201C>A p.I67= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV100399989, COSV56634499; called by muse, mutect2, varscan2
- OR13G1 | c.162G>T p.T54= | Silent (SNP) | VAF 17/55 reads (31%) | catalogued as COSV62943288, COSV62943347; called by muse, mutect2, varscan2
- OR1J4 | c.294A>G p.V98= | Silent (SNP) | VAF 57/183 reads (31%) | catalogued as COSV61590254; called by muse, mutect2, varscan2
- OR4D6 | c.660C>T p.V220= | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV55660899; called by muse, mutect2, varscan2
- OR9G4 | c.837C>A p.T279= | Silent (SNP) | VAF 12/88 reads (14%) | catalogued as COSV57249577, COSV57249710; called by muse, mutect2, varscan2
- PARP3 | c.432G>A p.V144= | Silent (SNP) | VAF 21/181 reads (12%) | catalogued as COSV51756269; called by muse, mutect2, varscan2
- PBDC1 | c.186G>T p.L62= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as COSV64896171; called by muse, mutect2, varscan2
- PCDHB14 | c.75G>A p.R25= | Silent (SNP) | VAF 10/52 reads (19%) | catalogued as rs1554288980, COSV53390924; called by muse, mutect2, varscan2
- PCDHB2 | c.69G>T p.L23= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as COSV52037160; called by muse, mutect2, varscan2
- PCDHB6 | c.1527C>T p.G509= | Silent (SNP) | VAF 44/310 reads (14%) | catalogued as COSV50724011; called by muse, varscan2
- PCDHB8 | c.1374C>A p.T458= | Silent (SNP) | VAF 37/382 reads (10%) | catalogued as COSV50809210; called by muse, varscan2
- PCDHGA3 | c.67C>T p.L23= | Silent (SNP) | VAF 44/276 reads (16%) | catalogued as COSV54019593; called by muse, mutect2, varscan2
- PCDHGA3 | c.2235G>T p.G745= | Silent (SNP) | VAF 18/150 reads (12%) | catalogued as COSV54019628; called by muse, mutect2, varscan2
- PDILT | c.1737A>G p.K579= | Silent (SNP) | VAF 38/183 reads (21%) | catalogued as COSV56704738; called by muse, mutect2, varscan2
- PLA1A | c.132T>C p.F44= | Silent (SNP) | VAF 34/197 reads (17%) | catalogued as COSV56333595; called by muse, mutect2, varscan2
- PLCH2 | c.2259C>A p.P753= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs370514223, COSV53948891; called by muse, varscan2
- PLXNC1 | c.4317C>T p.D1439= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs113780946, COSV51582397; called by muse, mutect2, varscan2
- PRG4 | c.1044G>A p.K348= | Silent (SNP) | VAF 55/195 reads (28%) | catalogued as COSV66604451; called by muse, mutect2, varscan2
- PTPRM | c.336G>A p.G112= | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs202244854, COSV100161241, COSV59878693; called by muse, mutect2, varscan2
- RANBP6 | c.558C>T p.D186= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as COSV52391326; called by muse, mutect2, varscan2
- RTTN | c.2364G>T p.G788= | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as COSV99730477; called by muse, mutect2
- SAMD14 | c.100C>A p.R34= | Silent (SNP) | VAF 7/74 reads (9%) | catalogued as COSV99557281; called by muse, mutect2
- SF3B1 | c.711T>C p.G237= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV59225523; called by muse, mutect2, varscan2
- SF3B3 | c.2004G>T p.G668= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV56790708; called by muse, mutect2
- SLC18A1 | c.906C>A p.I302= | Silent (SNP) | VAF 20/95 reads (21%) | catalogued as COSV52350965; called by muse, mutect2, varscan2
- SLC27A6 | c.1279C>A p.R427= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as COSV52484769, COSV52487137; called by muse, mutect2, varscan2
- SLC3A1 | c.690A>G p.T230= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV53224609; called by muse, mutect2, varscan2
- SLITRK3 | c.2610G>T p.V870= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV53852777; called by muse, mutect2, varscan2
- SPATS1 | c.36G>A p.R12= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV55824736; called by muse, mutect2, varscan2
- SPHKAP | c.858T>A p.S286= | Silent (SNP) | VAF 25/229 reads (11%) | catalogued as COSV60892172; called by muse, mutect2, varscan2
- STARD8 | c.2850G>A p.V950= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV52931963; called by muse, mutect2, varscan2
- SYNE1 | c.5757A>G p.L1919= (on ENST00000367255 / NM_182961.4; = p.L1926= on NM_033071.3) | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV55084604; called by muse, mutect2, varscan2
- TBX18 | c.1176C>T p.G392= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV63738073; called by muse, mutect2, varscan2
- THG1L | c.168G>A p.R56= | Silent (SNP) | VAF 30/211 reads (14%) | catalogued as rs1272950854, COSV51453549; called by muse, mutect2, varscan2
- TMEM131L | c.2982C>T p.A994= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as rs764864378, COSV53649761; called by muse, mutect2, varscan2
- TNNI3 | c.543C>T p.T181= | Silent (SNP) | VAF 26/128 reads (20%) | catalogued as rs926550445, COSV52573370; called by muse, varscan2
- TOX2 | c.627C>A p.T209= (on ENST00000358131 / NM_001098798.2; = p.T158= on NM_032883.3) | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs751507526, COSV100364868, COSV57894338; called by muse, mutect2, varscan2
- TPSD1 | c.657G>T p.A219= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV52975886, COSV52978283, COSV99273530; called by muse, mutect2, varscan2
- TPSD1 | c.702C>A p.P234= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV52978294; called by muse, mutect2, varscan2
- TTN | c.61281C>A p.T20427= (on ENST00000591111; = p.T13003= on NM_003319.4) | Silent (SNP) | VAF 15/111 reads (14%) | catalogued as rs1470155716, COSV60302604; called by muse, mutect2, varscan2
- URGCP | c.2202A>G p.T734= (on ENST00000453200 / NM_001077663.3; = p.T725= on NM_017920.4) | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV56252164; called by muse, mutect2, varscan2
- ZNF536 | c.3798G>T p.S1266= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as rs767947085, COSV62833018; called by mutect2, varscan2
- ZNF578 | c.1686C>T p.S562= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs376877936; called by muse, mutect2, varscan2
- ZNF835 | c.1371C>T p.N457= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV73379720; called by muse, mutect2, varscan2
- AC024940.1 | n.2042G>A | RNA (SNP) | VAF 14/200 reads (7%) | catalogued as rs188062266; called by muse, mutect2
- CPLANE1 | c.*5814C>T | 3'UTR (SNP) | VAF 16/164 reads (10%) | catalogued as rs1368027920, COSV57072339; called by muse, mutect2
- FOLH1B | n.1304A>T | RNA (SNP) | VAF 9/42 reads (21%) | called by muse, mutect2, varscan2
- LINC00303 | n.215C>A | RNA (SNP) | VAF 6/13 reads (46%) | called by muse, varscan2
- MIR20B | n.26T>A | RNA (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- OFCC1 | n.393-2884G>T | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- POLA1 | c.2947-20984G>T | Intron (SNP) | VAF 35/161 reads (22%) | called by muse, mutect2, varscan2
- SELENOI | c.-74C>T | 5'UTR (SNP) | VAF 3/21 reads (14%) | catalogued as COSV53146558; called by muse, mutect2
- USH1C | c.1285-7689C>T | Intron (SNP) | VAF 6/32 reads (19%) | catalogued as rs755766185, COSV99139188; called by muse, mutect2, varscan2
- XIRP2 | c.*986G>A | 3'UTR (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99736435; called by muse, mutect2, varscan2
- XIST | n.7252A>T | RNA (SNP) | VAF 21/174 reads (12%) | called by muse, mutect2, varscan2
